Somatic mutation profile of tumor specimen 942e63bd-84d6-4227-b3de-03e182 (aliquot 942e63bd-84d6-4227-b3de-03e182_D6) from CPTAC case 05BR038, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 52.1 years (19,040 days).
Specimen 942e63bd-84d6-4227-b3de-03e182: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e26b008f-eb27-4287-8f4c-ef3080258421.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 532b795c-c9cf-463e-85c5-32dfbe (Blood Derived Normal), aliquot 532b795c-c9cf-463e-85c5-32dfbe_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5cc6701-fd66-4c5d-aac2-c813c5c2495e

The open-access MAF lists 387 somatic variants for this specimen: 247 protein-altering or splice-affecting, 92 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 215, Silent 92, Intron 27, Nonsense Mutation 24, 3'UTR 9, 5'UTR 7, Splice Site 5, 5'Flank 2, 3'Flank 2, In Frame Del 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.305_307del p.I102_E103delinsK | In Frame Del (DEL) | VAF 50/157 reads (32%) | hotspot (GDC flag); catalogued as COSV55952768; called by mutect2, pindel, varscan2
- RHOA | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as rs1057519951, COSV69041613, COSV69042111, COSV69043712; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 174/568 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- ABCC2 | c.3787G>C p.E1263Q | Missense Mutation (SNP) | VAF 14/410 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV64987833, COSV64988000; called by muse, mutect2
- ABRA | c.930G>A p.M310I | Missense Mutation (SNP) | VAF 52/820 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61733281; called by muse, mutect2
- ADGRF4 | c.1608C>G p.I536M | Missense Mutation (SNP) | VAF 26/704 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV51955668, COSV51957272; called by muse, mutect2
- AKAP6 | c.4354G>A p.D1452N | Missense Mutation (SNP) | VAF 13/309 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.198); catalogued as rs1437896092, COSV55213495; called by muse, mutect2
- ANAPC7 | c.491C>G p.S164* | Nonsense Mutation (SNP) | VAF 8/83 reads (10%) | catalogued as COSV101484819; called by muse, mutect2, varscan2
- ANK1 | c.2254C>G p.L752V | Missense Mutation (SNP) | VAF 44/846 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.099); catalogued as rs1180261075; called by muse, mutect2
- AP1M1 | c.186C>G p.H62Q | Missense Mutation (SNP) | VAF 12/198 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.839); catalogued as rs1317219147; called by muse, mutect2
- BAZ2B | c.2065C>T p.H689Y | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.295); catalogued as rs1307820042; called by muse, mutect2
- BAZ2B | c.1661C>G p.S554C | Missense Mutation (SNP) | VAF 42/474 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.299); catalogued as COSV58595093; called by muse, mutect2
- BGN | c.375G>C p.K125N | Missense Mutation (SNP) | VAF 18/715 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.068); catalogued as COSV59038266; called by muse, mutect2
- BMS1 | c.406G>C p.D136H | Missense Mutation (SNP) | VAF 45/268 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs916334894; called by muse, mutect2, varscan2
- CDH5 | c.1918G>A p.E640K | Missense Mutation (SNP) | VAF 40/246 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777441392; called by muse, varscan2
- CDKN1B | c.193C>T p.Q65* | Nonsense Mutation (SNP) | VAF 18/476 reads (4%) | catalogued as COSV99963743; called by muse, mutect2
- CHGB | c.1224G>C p.E408D | Missense Mutation (SNP) | VAF 12/378 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.054); catalogued as COSV66759516; called by muse, mutect2
- CHPF | c.886G>T p.E296* | Nonsense Mutation (SNP) | VAF 4/36 reads (11%) | catalogued as COSV60535456; called by muse, varscan2
- CLIP2 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 26/764 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as rs782756175, COSV99791047; called by muse, mutect2
- CPZ | c.1178C>T p.S393F (on ENST00000360986 / NM_001014447.3; = p.S382F on NM_003652.3) | Missense Mutation (SNP) | VAF 59/231 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59923976; called by muse, mutect2, varscan2
- CSNK1A1L | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 134/541 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); catalogued as COSV65789414, COSV65789570; called by muse, mutect2, varscan2
- CUL4B | c.2638C>G p.P880A | Missense Mutation (SNP) | VAF 20/263 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV60689043; called by muse, mutect2
- CYP2C19 | c.1222G>C p.D408H | Missense Mutation (SNP) | VAF 33/278 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64907433; called by muse, mutect2, varscan2
- DAPK1 | c.3058G>A p.E1020K | Missense Mutation (SNP) | VAF 44/195 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs752014007; called by muse, mutect2, varscan2
- EDEM1 | c.707C>T p.S236F | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56582931; called by muse, mutect2, varscan2
- ERBB4 | c.2063G>A p.R688K | Missense Mutation (SNP) | VAF 12/155 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); catalogued as COSV53543802; called by muse, mutect2
- F8 | c.4326G>C p.K1442N | Missense Mutation (SNP) | VAF 17/348 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV100811797; called by muse, mutect2
- FGF23 | c.471C>A p.F157L | Missense Mutation (SNP) | VAF 122/639 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM144430, COSV52975760; called by muse, mutect2, varscan2
- FLRT2 | c.1468C>G p.R490G | Missense Mutation (SNP) | VAF 100/433 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as COSV58139372; called by muse, mutect2, varscan2
- FLT1 | c.3374C>G p.S1125C | Missense Mutation (SNP) | VAF 18/512 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV56720280, COSV56727351, COSV99152556; called by muse, mutect2
- FURIN | c.1847C>T p.P616L | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as rs774671374; called by muse, mutect2, varscan2
- GDF10 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 30/688 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs781814156; called by muse, mutect2
- GIPC1 | c.608G>A p.R203Q | Missense Mutation (SNP) | VAF 68/485 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs747875302; called by muse, mutect2, varscan2
- GLRA4 | c.748C>T p.H250Y | Missense Mutation (SNP) | VAF 18/237 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV65455227; called by muse, mutect2
- GRB10 | c.398C>A p.S133* | Nonsense Mutation (SNP) | VAF 111/734 reads (15%) | catalogued as COSV60008734; called by muse, mutect2, varscan2
- HMCN1 | c.3929G>C p.R1310T | Missense Mutation (SNP) | VAF 8/196 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0.174); catalogued as COSV54881200; called by muse, mutect2
- IQSEC1 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs1451166177; called by muse, mutect2, varscan2
- KIFC2 | c.1837C>G p.P613A | Missense Mutation (SNP) | VAF 47/347 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.069); catalogued as rs757007735, COSV56762796, COSV56763278; called by muse, mutect2, varscan2
- KLRC2 | c.418G>T p.E140* | Nonsense Mutation (SNP) | VAF 39/142 reads (27%) | catalogued as COSV101122757; called by muse, mutect2, varscan2
- KMT2E | c.3307G>C p.E1103Q | Missense Mutation (SNP) | VAF 13/489 reads (3%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.867); catalogued as COSV57577936; called by muse, mutect2
- LCP2 | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.37); catalogued as rs781737759; called by muse, mutect2, varscan2
- LRRC56 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 53/166 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs367633088; called by muse, mutect2, varscan2
- LRRFIP1 | c.601G>A p.E201K (on ENST00000392000 / NM_001137552.2; = p.E177K on NM_004735.4) | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55252636; called by muse, mutect2, varscan2
- LZTR1 | c.1842G>A p.M614I | Missense Mutation (SNP) | VAF 38/221 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs763044573; called by muse, mutect2, varscan2
- MAP2K4 | c.669G>C p.L223F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100796602; called by muse, mutect2, varscan2
- MAP2K4 | c.701A>G p.N234S | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100796170, COSV62260090; called by muse, mutect2, varscan2
- MAP3K1 | c.1193C>G p.S398* | Nonsense Mutation (SNP) | VAF 58/315 reads (18%) | catalogued as COSV68123971; called by muse, mutect2, varscan2
- MAP3K1 | c.3047C>G p.S1016C | Missense Mutation (SNP) | VAF 90/556 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs766857345, COSV68123746; called by muse, mutect2, varscan2
- MDC1 | c.2731C>T p.P911S | Missense Mutation (SNP) | VAF 58/469 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs750271934; called by muse, mutect2, varscan2
- MTREX | c.2602G>C p.D868H | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57926231; called by muse, mutect2
- MUC1 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 76/279 reads (27%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.222); catalogued as rs767990583; called by muse, mutect2, varscan2
- MUC19 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.844); catalogued as rs1188879179; called by muse, mutect2
- NBPF1 | c.161G>C p.R54P | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.227); catalogued as rs753365495; called by muse, mutect2, varscan2
- NCOA2 | c.3699G>C p.Q1233H | Missense Mutation (SNP) | VAF 74/359 reads (21%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV51222996; called by muse, mutect2, varscan2
- NOTCH1 | c.5402C>T p.S1801L | Missense Mutation (SNP) | VAF 93/701 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs376236888; called by muse, mutect2, varscan2
- OR9K2 | c.671C>G p.S224C (on ENST00000305377; = p.S202C on NM_001005243.1) | Missense Mutation (SNP) | VAF 16/497 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV59533587; called by muse, mutect2
- PCBP1 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 55/357 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.023); catalogued as COSV57851758; called by muse, mutect2, varscan2
- PCDHA12 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 56/930 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.224); catalogued as rs1462172871; called by muse, mutect2
- PDXDC1 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 15/202 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.545); catalogued as COSV57911291; called by muse, mutect2
- PEG3 | c.4374T>G p.I1458M | Missense Mutation (SNP) | VAF 18/584 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.344); catalogued as COSV99689034; called by muse, mutect2
- PFDN6 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | catalogued as COSV101004789; called by muse, mutect2
- POLH | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 59/346 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV64779285; called by muse, mutect2, varscan2
- PPCS | c.338C>A p.S113* | Nonsense Mutation (SNP) | VAF 18/609 reads (3%) | catalogued as COSV65333748; called by muse, mutect2
- PPP1R26 | c.983C>T p.S328L | Missense Mutation (SNP) | VAF 40/275 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV63356158; called by muse, mutect2, varscan2
- PRRC2C | c.801G>A p.M267I (on ENST00000367742; = p.M265I on NM_015172.4) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV58901230; called by muse, mutect2, varscan2
- PTPRT | c.2551C>T p.R851C | Missense Mutation (SNP) | VAF 72/255 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as rs757562149, COSV61958681; called by muse, mutect2, varscan2
- PZP | c.303C>G p.F101L | Missense Mutation (SNP) | VAF 30/192 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV99740158; called by muse, mutect2, varscan2
- RELN | c.5077G>C p.D1693H | Missense Mutation (SNP) | VAF 16/372 reads (4%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV59001001; called by muse, mutect2
- RPS13 | c.150C>T p.I50= | Splice Region (SNP) | VAF 41/165 reads (25%) | catalogued as rs769233177; called by muse, mutect2, varscan2
- SCN4A | c.4699G>A p.D1567N | Missense Mutation (SNP) | VAF 144/365 reads (39%) | SIFT tolerated (0.9); PolyPhen benign (0.012); catalogued as rs768071512; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH3TC1 | c.2201C>G p.S734* | Nonsense Mutation (SNP) | VAF 22/696 reads (3%) | catalogued as COSV99794255; called by muse, mutect2
- SLC9A9 | c.1469G>A p.R490K | Missense Mutation (SNP) | VAF 16/453 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.049); catalogued as rs1324308370; called by muse, mutect2
- SLIT1 | c.3244G>A p.E1082K | Missense Mutation (SNP) | VAF 36/299 reads (12%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs765166328; called by muse, mutect2, varscan2
- SPATS1 | c.154G>A p.D52N | Missense Mutation (SNP) | VAF 18/190 reads (9%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.714); catalogued as COSV55823979; called by muse, mutect2, varscan2
- SPEN | c.5039C>G p.S1680* | Nonsense Mutation (SNP) | VAF 23/180 reads (13%) | catalogued as COSV65367268; called by muse, mutect2, varscan2
- SPEN | c.9970C>T p.Q3324* | Nonsense Mutation (SNP) | VAF 28/68 reads (41%) | catalogued as COSV65361783; called by muse, mutect2, varscan2
- SPINK5 | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 108/372 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472020500; called by muse, mutect2, varscan2
- SPOPL | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.634); catalogued as COSV54512928; called by muse, mutect2, varscan2
- SYNE2 | c.18130G>A p.E6044K | Missense Mutation (SNP) | VAF 119/436 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59942439; called by muse, mutect2, varscan2
- TENM4 | c.5210C>T p.T1737I | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as rs1425840299; called by muse, mutect2
- TLN2 | c.6110G>A p.G2037E | Missense Mutation (SNP) | VAF 56/374 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); catalogued as COSV60897301; called by muse, mutect2, varscan2
- TNNC1 | c.56-1G>A p.X19_splice | Splice Site (SNP) | VAF 131/573 reads (23%) | catalogued as COSV99234777; called by muse, mutect2, varscan2
- TTC14 | c.1753G>C p.E585Q | Missense Mutation (SNP) | VAF 67/356 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as COSV56013645; called by muse, mutect2, varscan2
- TTC28 | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 76/511 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.703); catalogued as rs867430519; called by muse, mutect2, varscan2
- TTN | c.2155G>A p.E719K (on ENST00000591111; = p.E673K on NM_003319.4) | Missense Mutation (SNP) | VAF 38/858 reads (4%) | PolyPhen benign (0.225); catalogued as rs765404174; called by muse, mutect2
- WDFY3 | c.4349G>C p.R1450T | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV55712414; called by muse, mutect2
- XRN2 | c.2770G>A p.D924N | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT tolerated, low confidence (0.34); PolyPhen probably damaging (0.956); catalogued as COSV65869403; called by muse, mutect2, varscan2
- ZDHHC20 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV100203378, COSV57184050; called by muse, mutect2
- ZFHX3 | c.5422C>T p.Q1808* | Nonsense Mutation (SNP) | VAF 62/165 reads (38%) | catalogued as COSV99200003; called by muse, mutect2, varscan2
- ZNF169 | c.1681C>T p.Q561* | Nonsense Mutation (SNP) | VAF 84/323 reads (26%) | catalogued as rs1289084595; called by muse, mutect2, varscan2
- ZNF229 | c.46C>G p.Q16E | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV52162441; called by mutect2, varscan2
- ZNF292 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 20/237 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as rs1179557918; called by muse, mutect2
- ZNF394 | c.170C>T p.S57L | Missense Mutation (SNP) | VAF 88/280 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.007); catalogued as rs1306098241, COSV58742940; called by muse, mutect2, varscan2
- ZNF529 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.313); catalogued as rs374952430; called by mutect2, varscan2
- ZNF607 | c.1711C>T p.R571C | Missense Mutation (SNP) | VAF 78/348 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.531); catalogued as rs763040448, COSV67697024; called by muse, mutect2, varscan2
- ABCA7 | c.6145G>A p.E2049K | Missense Mutation (SNP) | VAF 71/395 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- ABCB1 | c.3806C>T p.S1269L | Missense Mutation (SNP) | VAF 21/673 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.497); called by muse, mutect2
- ABCB6 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABRA | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 55/895 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- AC004593.2 | c.883C>T p.H295Y | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ACTL8 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 12/395 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.049); called by muse, mutect2
- ADAL | c.910C>G p.Q304E (on ENST00000562188 / NM_001324366.2; = p.Q277E on NM_001159280.3) | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.25); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- AGAP4 | c.448C>T p.H150Y | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- AGGF1 | c.1523G>A p.G508E | Missense Mutation (SNP) | VAF 67/337 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALPK1 | c.1608G>C p.R536S | Missense Mutation (SNP) | VAF 11/259 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2
- ANKHD1 | c.3151-1G>C p.X1051_splice | Splice Site (SNP) | VAF 6/147 reads (4%) | called by muse, mutect2
- ANKRD12 | c.5452G>A p.D1818N | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ANKRD52 | c.859C>G p.L287V | Missense Mutation (SNP) | VAF 51/355 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- APBB1 | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 12/287 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2
- APOB | c.879G>T p.K293N | Missense Mutation (SNP) | VAF 156/707 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ARMCX6 | c.253G>C p.E85Q | Missense Mutation (SNP) | VAF 115/374 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- ASTN2 | c.3538G>A p.E1180K (on ENST00000313400 / NM_001365069.1; = p.E1129K on NM_014010.5) | Missense Mutation (SNP) | VAF 46/228 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- ATP8B3 | c.1710C>G p.I570M | Missense Mutation (SNP) | VAF 83/270 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- ATRIP | c.2239C>T p.Q747* (on ENST00000320211 / NM_130384.3; = p.Q720* on NM_032166.4) | Nonsense Mutation (SNP) | VAF 65/315 reads (21%) | called by muse, mutect2, varscan2
- BABAM2 | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.844); called by muse, mutect2
- BCL10 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.009); called by muse, mutect2
- BHLHE40 | c.1040C>T p.S347L | Missense Mutation (SNP) | VAF 17/432 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.392); called by muse, mutect2
- BPTF | c.3472G>C p.E1158Q | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- C10orf88 | c.1334G>C p.R445T | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C16orf82 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 26/602 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); called by muse, mutect2
- C2orf16 | c.298C>G p.Q100E | Missense Mutation (SNP) | VAF 14/272 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.558); called by muse, mutect2
- CABS1 | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 13/185 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.063); called by muse, mutect2
- CDC42BPB | c.5035C>G p.P1679A | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CEACAM21 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.198); called by muse, mutect2
- CEACAM5 | c.911C>G p.S304* | Nonsense Mutation (SNP) | VAF 23/204 reads (11%) | called by muse, mutect2, varscan2
- CKB | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 62/208 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CNTNAP5 | c.3391G>C p.E1131Q | Missense Mutation (SNP) | VAF 5/101 reads (5%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.494); called by muse, mutect2
- COL28A1 | c.3069G>C p.L1023F | Missense Mutation (SNP) | VAF 21/131 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRELD2 | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CRK | c.119C>G p.S40W | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMRT1 | c.883C>A p.P295T | Missense Mutation (SNP) | VAF 72/500 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- DNAH1 | c.2424C>G p.I808M | Missense Mutation (SNP) | VAF 40/966 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- DNAJC13 | c.6151C>T p.L2051F | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- DOCK5 | c.5266-1G>C p.X1756_splice | Splice Site (SNP) | VAF 9/215 reads (4%) | called by muse, mutect2
- DSCAM | c.1421C>G p.S474C | Missense Mutation (SNP) | VAF 19/540 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.353); called by muse, mutect2
- DSPP | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 16/494 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- DTX1 | c.428C>G p.S143* | Nonsense Mutation (SNP) | VAF 24/348 reads (7%) | called by muse, mutect2
- ECPAS | c.4432C>A p.L1478M | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); called by muse, mutect2
- EME2 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 74/259 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.005); called by mutect2, varscan2
- ENTR1 | c.1056C>G p.I352M (on ENST00000357365 / NM_001039707.2; = p.I329M on NM_006643.4) | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.017); called by muse, mutect2
- EPB41L3 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 70/387 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ERCC6 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 22/590 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- FBL | c.873G>A p.M291I | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT tolerated (0.67); PolyPhen benign (0.046); called by muse, mutect2
- FBXO34 | c.267G>C p.K89N | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, varscan2
- FNIP1 | c.917C>G p.S306C | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- GAN | c.53G>C p.R18P | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.553); called by mutect2, varscan2
- GFRA3 | c.715T>C p.C239R | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GLDC | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GOLGB1 | c.9544G>C p.E3182Q | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- GPATCH4 | c.32-1G>C p.X11_splice | Splice Site (SNP) | VAF 13/97 reads (13%) | called by muse, mutect2, varscan2
- GPR155 | c.1425G>C p.E475D | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2
- HACD1 | c.370C>T p.L124F | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- HCFC1 | c.706G>A p.D236N | Missense Mutation (SNP) | VAF 13/402 reads (3%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.708); called by muse, mutect2
- HECTD1 | c.19G>A p.D7N | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- HELB | c.2782G>C p.E928Q | Missense Mutation (SNP) | VAF 22/566 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2
- HIVEP1 | c.6109G>C p.E2037Q | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); called by muse, mutect2
- IGFN1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); called by muse, mutect2
- INCENP | c.1606G>A p.E536K (on ENST00000394818 / NM_001040694.2; = p.E532K on NM_020238.3) | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- IRX5 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 100/427 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- ITGB6 | c.211C>G p.Q71E | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KIF26A | c.5222C>A p.S1741Y | Missense Mutation (SNP) | VAF 12/289 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2
- KLHL8 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- KRT82 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.148); called by muse, mutect2
- KTN1 | c.3472G>A p.E1158K (on ENST00000395314 / NM_001271014.2; = p.E1129K on NM_004986.4) | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LENG1 | c.705G>C p.E235D | Missense Mutation (SNP) | VAF 14/410 reads (3%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.956); called by muse, mutect2
- LRCH2 | c.980C>G p.S327* | Nonsense Mutation (SNP) | VAF 5/98 reads (5%) | called by muse, mutect2
- LRRC8C | c.1081G>T p.D361Y | Missense Mutation (SNP) | VAF 48/369 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- LYPD3 | c.39C>G p.I13M | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LYST | c.5682G>C p.E1894D | Missense Mutation (SNP) | VAF 11/163 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.13); called by muse, mutect2
- MACROH2A1 | c.982C>G p.Q328E (on ENST00000510038; = p.Q327E on NM_004893.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/295 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.088); called by muse, mutect2
- MED12L | c.4381C>G p.L1461V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MKI67 | c.7720G>T p.E2574* | Nonsense Mutation (SNP) | VAF 51/442 reads (12%) | called by muse, mutect2, varscan2
- MXRA5 | c.2941G>A p.D981N | Missense Mutation (SNP) | VAF 71/380 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- NBPF12 | c.1318G>A p.D440N | Missense Mutation (SNP) | VAF 39/218 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- NEFM | c.2188G>C p.E730Q | Missense Mutation (SNP) | VAF 11/257 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.07); called by muse, mutect2
- NIBAN3 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOSTRIN | c.616G>C p.E206Q (on ENST00000317647 / NM_001039724.4; = p.E128Q on NM_052946.3) | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOX3 | c.782C>G p.S261C | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NPHS1 | c.1755G>C p.E585D | Missense Mutation (SNP) | VAF 28/340 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.174); called by muse, mutect2
- NRAP | c.2269C>T p.Q757* (on ENST00000359988 / NM_001322945.2; = p.Q722* on NM_006175.4) | Nonsense Mutation (SNP) | VAF 45/199 reads (23%) | called by muse, varscan2
- NRM | c.703G>A p.D235N | Missense Mutation (SNP) | VAF 60/296 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- NUP214 | c.1892C>T p.S631L | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR7A17 | c.125A>T p.N42I | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PANX2 | c.412C>T p.P138S | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PAX2 | c.667C>G p.L223V | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCSK4 | c.1187G>C p.R396T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); called by muse, mutect2, varscan2
- PEX1 | c.3076C>G p.L1026V | Missense Mutation (SNP) | VAF 59/230 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PHF12 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 35/692 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0.015); called by muse, mutect2
- PITPNM3 | c.1519C>G p.Q507E | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT tolerated (0.99); PolyPhen benign (0.054); called by muse, mutect2
- PKD1 | c.10345G>C p.E3449Q (on ENST00000262304 / NM_001009944.3; = p.E3448Q on NM_000296.4) | Missense Mutation (SNP) | VAF 95/617 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- POU5F1B | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 17/348 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.265); called by muse, mutect2
- PTPN23 | c.4789A>C p.K1597Q | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- PTPRJ | c.2515G>C p.G839R | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.85); called by muse, mutect2
- PTPRJ | c.2516G>T p.G839V | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); called by muse, mutect2
- PTPRK | c.263G>C p.G88A | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RIF1 | c.6968G>C p.R2323T | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- RIMS1 | c.1045G>C p.E349Q | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.464); called by muse, mutect2
- RNF216 | c.2049C>G p.I683M (on ENST00000425013 / NM_207116.3; = p.I740M on NM_207111.4) | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.293); called by muse, mutect2
- ROCK1 | c.3223G>A p.E1075K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- RTEL1 | c.700-1G>C p.X234_splice | Splice Site (SNP) | VAF 28/176 reads (16%) | called by muse, mutect2, varscan2
- RTL9 | c.2747G>A p.R916K | Missense Mutation (SNP) | VAF 35/476 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.418); called by muse, mutect2
- SCN2A | c.5609G>C p.G1870A | Missense Mutation (SNP) | VAF 17/527 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.219); called by muse, mutect2
- SCN7A | c.3642G>C p.Q1214H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- SCUBE3 | c.492G>C p.K164N | Missense Mutation (SNP) | VAF 12/312 reads (4%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); called by muse, mutect2
- SERPING1 | c.786C>G p.I262M | Missense Mutation (SNP) | VAF 74/567 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SIPA1L1 | c.1376G>C p.G459A | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- SLC22A3 | c.308C>G p.S103C | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SLC27A5 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 49/141 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- SLC30A1 | c.1434G>C p.K478N | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.017); called by muse, mutect2
- SLC39A6 | c.593G>C p.G198A | Missense Mutation (SNP) | VAF 48/613 reads (8%) | SIFT tolerated (0.3); PolyPhen benign (0.117); called by muse, mutect2
- SLC8A2 | c.1127C>T p.S376L | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.06); called by muse, mutect2
- SLF2 | c.1046G>C p.R349T | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- SMC1B | c.2972C>G p.S991C | Missense Mutation (SNP) | VAF 23/145 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- SPATA31E1 | c.4021G>A p.E1341K | Missense Mutation (SNP) | VAF 122/670 reads (18%) | SIFT tolerated (0.81); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- SPTAN1 | c.7122C>G p.I2374M | Missense Mutation (SNP) | VAF 24/928 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- SRBD1 | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.029); called by muse, mutect2
- STARD9 | c.6628C>A p.L2210M | Missense Mutation (SNP) | VAF 72/348 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); called by muse, varscan2
- STARD9 | c.11894G>A p.R3965K | Missense Mutation (SNP) | VAF 67/363 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STKLD1 | c.1881C>G p.I627M | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TACSTD2 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 52/320 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- TBC1D1 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 50/367 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TCF20 | c.4406C>T p.S1469L | Missense Mutation (SNP) | VAF 26/538 reads (5%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.343); called by muse, mutect2
- TCHHL1 | c.859A>G p.N287D | Missense Mutation (SNP) | VAF 95/358 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM132B | c.1379C>G p.S460C | Missense Mutation (SNP) | VAF 18/399 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); called by muse, mutect2
- TMEM171 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); called by muse, mutect2
- TOR1AIP1 | c.1099G>A p.E367K | Missense Mutation (SNP) | VAF 56/454 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- TOR1B | c.59G>C p.R20P | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPR | c.6314G>C p.R2105P | Missense Mutation (SNP) | VAF 18/176 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.133); called by muse, mutect2
- TRAIP | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- TRAM1L1 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 91/267 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TTI1 | c.1388C>G p.S463* | Nonsense Mutation (SNP) | VAF 24/356 reads (7%) | called by muse, mutect2
- TTLL2 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 96/280 reads (34%) | called by mutect2, varscan2
- TUBA1A | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 20/506 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.922); called by muse, mutect2
- UBE2F | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 13/206 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- UBR4 | c.10037C>A p.S3346Y | Missense Mutation (SNP) | VAF 47/474 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2
- UNC80 | c.4578G>C p.Q1526H | Missense Mutation (SNP) | VAF 8/195 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.138); called by muse, mutect2
- VARS2 | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- VWDE | c.3346C>T p.Q1116* | Nonsense Mutation (SNP) | VAF 18/517 reads (3%) | called by muse, mutect2
- WDR26 | c.1714C>T p.Q572* (on ENST00000414423 / NM_001379403.1; = p.Q472* on NM_025160.7) | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- ZAP70 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 35/450 reads (8%) | called by muse, mutect2
- ZKSCAN2 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF169 | c.482C>G p.S161C | Missense Mutation (SNP) | VAF 16/436 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.775); called by muse, mutect2
- ZNF215 | c.1083G>C p.L361F | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2
- ZNF233 | c.1581G>C p.Q527H | Missense Mutation (SNP) | VAF 40/310 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ZNF493 | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZNF555 | c.631C>T p.R211C | Missense Mutation (SNP) | VAF 40/752 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.025); called by muse, mutect2
- ZNF599 | c.836G>C p.G279A | Missense Mutation (SNP) | VAF 106/708 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- A4GALT | c.370C>T p.L124= | Silent (SNP) | VAF 69/376 reads (18%) | catalogued as rs769360984; called by muse, mutect2, varscan2
- ACTA1 | c.69C>T p.F23= | Silent (SNP) | VAF 20/599 reads (3%) | catalogued as rs1339913000, COSV64202957; ClinVar: likely benign; called by muse, mutect2
- ADCY10 | c.3354C>G p.L1118= | Silent (SNP) | VAF 18/606 reads (3%) | called by muse, mutect2
- ADGRE1 | c.2064G>C p.V688= | Silent (SNP) | VAF 28/630 reads (4%) | catalogued as COSV51675527, COSV51677427; called by muse, mutect2
- AGGF1 | c.2121T>A p.P707= | Silent (SNP) | VAF 53/215 reads (25%) | called by muse, mutect2, varscan2
- AHNAK2 | c.6072C>G p.L2024= | Silent (SNP) | VAF 19/524 reads (4%) | called by muse, mutect2
- AL645922.1 | c.2664C>T p.L888= | Silent (SNP) | VAF 61/477 reads (13%) | called by muse, mutect2, varscan2
- ANO5 | c.924A>G p.G308= | Silent (SNP) | VAF 8/178 reads (4%) | called by muse, mutect2
- AP002512.3 | c.1089C>G p.L363= | Silent (SNP) | VAF 16/444 reads (4%) | catalogued as COSV54406716; called by muse, mutect2
- APBA1 | c.1686G>A p.R562= | Silent (SNP) | VAF 60/404 reads (15%) | catalogued as rs1190546229; called by muse, mutect2, varscan2
- ARHGAP31 | c.2499C>T p.L833= | Silent (SNP) | VAF 39/853 reads (5%) | called by muse, mutect2
- ARHGAP45 | c.213C>T p.H71= | Silent (SNP) | VAF 138/476 reads (29%) | catalogued as rs774974451; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.153G>A p.K51= | Silent (SNP) | VAF 55/307 reads (18%) | called by muse, mutect2, varscan2
- ATP2A2 | c.1956C>T p.F652= | Silent (SNP) | VAF 79/337 reads (23%) | called by muse, mutect2, varscan2
- ATP6V0B | c.16C>T p.L6= | Silent (SNP) | VAF 18/54 reads (33%) | called by muse, mutect2, varscan2
- ATXN7L1 | c.936C>T p.L312= | Silent (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- C10orf53 | c.171G>A p.V57= | Silent (SNP) | VAF 52/222 reads (23%) | catalogued as COSV65107998; called by muse, mutect2, varscan2
- C2CD4C | c.450C>T p.F150= | Silent (SNP) | VAF 40/255 reads (16%) | catalogued as rs542233116, COSV59966569; called by muse, mutect2, varscan2
- CACNA1F | c.2586G>A p.K862= | Silent (SNP) | VAF 40/800 reads (5%) | called by muse, mutect2
- CCDC88C | c.4923C>G p.L1641= | Silent (SNP) | VAF 29/186 reads (16%) | catalogued as rs1463779042; called by muse, mutect2, varscan2
- CHRM1 | c.1260C>G p.L420= | Silent (SNP) | VAF 18/512 reads (4%) | catalogued as rs1565264230, COSV100186045; called by muse, mutect2
- CKAP4 | c.765C>T p.F255= | Silent (SNP) | VAF 153/634 reads (24%) | catalogued as COSV65172530; called by muse, mutect2, varscan2
- CLCN6 | c.366G>A p.Q122= | Silent (SNP) | VAF 35/111 reads (32%) | catalogued as COSV56739364, COSV56740070; called by muse, mutect2, varscan2
- COG2 | c.2001G>C p.L667= | Silent (SNP) | VAF 18/196 reads (9%) | called by muse, mutect2
- CYB561D1 | c.111C>T p.F37= | Silent (SNP) | VAF 29/144 reads (20%) | called by muse, mutect2, varscan2
- DDX54 | c.1089G>A p.V363= | Silent (SNP) | VAF 33/285 reads (12%) | catalogued as rs1478521970; called by muse, mutect2, varscan2
- DDX6 | c.555C>T p.I185= | Silent (SNP) | VAF 26/137 reads (19%) | called by muse, mutect2, varscan2
- ECSIT | c.600G>C p.L200= | Silent (SNP) | VAF 108/470 reads (23%) | called by muse, mutect2, varscan2
- EFCAB14 | c.729G>A p.Q243= | Silent (SNP) | VAF 23/155 reads (15%) | called by muse, mutect2, varscan2
- FAT1 | c.10746C>G p.L3582= | Silent (SNP) | VAF 30/490 reads (6%) | called by muse, mutect2
- FBP2 | c.216G>A p.K72= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV64694412; called by muse, mutect2
- GALNT3 | c.1713G>A p.L571= | Silent (SNP) | VAF 23/482 reads (5%) | catalogued as COSV67062775; called by muse, mutect2
- GALT | c.423C>T p.L141= | Silent (SNP) | VAF 26/810 reads (3%) | called by muse, mutect2
- GCN1 | c.6930G>C p.L2310= | Silent (SNP) | VAF 16/590 reads (3%) | catalogued as COSV100326242; called by muse, mutect2
- GDF10 | c.73C>T p.L25= | Silent (SNP) | VAF 62/348 reads (18%) | called by muse, mutect2, varscan2
- GMCL2 | c.768C>T p.V256= | Silent (SNP) | VAF 18/404 reads (4%) | called by muse, mutect2
- GOLGA2 | c.2535G>C p.L845= | Silent (SNP) | VAF 39/315 reads (12%) | called by muse, mutect2, varscan2
- GRM7 | c.2562C>G p.L854= | Silent (SNP) | VAF 21/842 reads (2%) | called by muse, mutect2
- GZMK | c.132C>T p.I44= | Silent (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- H6PD | c.1500C>G p.L500= | Silent (SNP) | VAF 28/758 reads (4%) | called by muse, mutect2
- HDHD3 | c.195G>A p.L65= | Silent (SNP) | VAF 64/293 reads (22%) | catalogued as rs940822463; called by muse, mutect2, varscan2
- HIVEP3 | c.411G>A p.G137= | Silent (SNP) | VAF 56/193 reads (29%) | called by muse, mutect2, varscan2
- HTR4 | c.406C>T p.L136= | Silent (SNP) | VAF 15/93 reads (16%) | called by muse, mutect2, varscan2
- IL4R | c.700C>T p.L234= | Silent (SNP) | VAF 22/372 reads (6%) | called by muse, mutect2
- IRS1 | c.3120C>T p.A1040= | Silent (SNP) | VAF 144/343 reads (42%) | called by muse, mutect2, varscan2
- KDM2B | c.3819C>T p.I1273= | Silent (SNP) | VAF 34/268 reads (13%) | catalogued as rs1555287738, COSV65645630; called by mutect2, varscan2
- KIAA1217 | c.88C>T p.L30= | Silent (SNP) | VAF 19/108 reads (18%) | called by muse, varscan2
- MAP3K6 | c.288C>T p.F96= | Silent (SNP) | VAF 7/15 reads (47%) | called by muse, mutect2, varscan2
- MCAT | c.1110C>T p.S370= | Silent (SNP) | VAF 123/497 reads (25%) | catalogued as rs781067666, COSV51793542; called by muse, mutect2, varscan2
- MECOM | c.420C>T p.F140= (on ENST00000468789 / NM_001105078.4; = p.F328= on NM_004991.4) | Silent (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- MXRA5 | c.2770C>T p.L924= | Silent (SNP) | VAF 65/305 reads (21%) | called by muse, mutect2, varscan2
- MYO15B | c.4815C>T p.I1605= | Silent (SNP) | VAF 39/156 reads (25%) | called by muse, mutect2, varscan2
- MYO3B | c.1767C>T p.F589= | Silent (SNP) | VAF 39/156 reads (25%) | catalogued as COSV100509925; called by muse, mutect2, varscan2
- MYO6 | c.585G>A p.A195= | Silent (SNP) | VAF 24/168 reads (14%) | catalogued as rs758269020, COSV100889371; called by muse, mutect2, varscan2
- NDST1 | c.1830C>T p.I610= | Silent (SNP) | VAF 79/575 reads (14%) | catalogued as rs771070360; called by muse, mutect2, varscan2
- NRDC | c.2709G>A p.L903= | Silent (SNP) | VAF 20/108 reads (19%) | called by muse, mutect2, varscan2
- NSF | c.2234G>A p.*745= | Silent (SNP) | VAF 19/68 reads (28%) | called by muse, mutect2, varscan2
- NTF4 | c.183G>A p.L61= | Silent (SNP) | VAF 46/267 reads (17%) | called by muse, mutect2, varscan2
- OOSP2 | c.240A>G p.T80= | Silent (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- OR4C13 | c.726C>T p.I242= | Silent (SNP) | VAF 10/267 reads (4%) | catalogued as COSV73648865; called by muse, mutect2
- PCDHGA7 | c.1575G>A p.L525= | Silent (SNP) | VAF 160/620 reads (26%) | catalogued as COSV99536698; called by muse, mutect2, varscan2
- PKHD1 | c.189G>A p.V63= | Silent (SNP) | VAF 44/388 reads (11%) | called by muse, mutect2, varscan2
- PLXNB2 | c.5070G>A p.V1690= | Silent (SNP) | VAF 61/219 reads (28%) | catalogued as rs746366608; called by muse, mutect2, varscan2
- PM20D1 | c.1380C>T p.F460= | Silent (SNP) | VAF 19/118 reads (16%) | called by muse, mutect2, varscan2
- POGLUT2 | c.795C>T p.I265= | Silent (SNP) | VAF 18/86 reads (21%) | catalogued as rs776464192, COSV65683011; called by muse, mutect2, varscan2
- PSMC1 | c.1098G>A p.Q366= | Silent (SNP) | VAF 27/131 reads (21%) | called by muse, mutect2, varscan2
- PTPRO | c.3249C>T p.I1083= (on ENST00000281171 / NM_030667.3; = p.I1055= on NM_002848.4) | Silent (SNP) | VAF 64/467 reads (14%) | called by muse, mutect2, varscan2
- RAB5IF | c.90G>A p.R30= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs1401149056; called by muse, varscan2
- RABGAP1L | c.1035G>A p.L345= (on ENST00000489615 / NM_001243765.2; = p.L228= on NM_001243764.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/101 reads (23%) | called by muse, mutect2, varscan2
- RADIL | c.3225C>G p.L1075= | Silent (SNP) | VAF 9/281 reads (3%) | catalogued as COSV68200935; called by muse, mutect2
- RNF157 | c.285G>A p.L95= | Silent (SNP) | VAF 8/143 reads (6%) | called by muse, mutect2
- SCN5A | c.2130G>A p.V710= | Silent (SNP) | VAF 19/188 reads (10%) | catalogued as rs866225028, COSV61123129; called by muse, mutect2
- SH3GL2 | c.276G>A p.L92= | Silent (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- SHOC2 | c.451C>T p.L151= | Silent (SNP) | VAF 20/602 reads (3%) | called by muse, mutect2
- SLC29A2 | c.1035G>C p.R345= | Silent (SNP) | VAF 100/631 reads (16%) | called by muse, mutect2, varscan2
- SNX25 | c.372C>T p.L124= | Silent (SNP) | VAF 19/141 reads (13%) | called by muse, mutect2, varscan2
- SPATC1 | c.951G>A p.V317= | Silent (SNP) | VAF 16/214 reads (7%) | called by muse, mutect2
- ST7 | c.1542C>T p.F514= (on ENST00000265437 / NM_021908.3; = p.F491= on NM_018412.4) | Silent (SNP) | VAF 49/184 reads (27%) | catalogued as COSV55381247; called by muse, mutect2, varscan2
- STARD9 | c.12579G>A p.K4193= | Silent (SNP) | VAF 58/254 reads (23%) | catalogued as rs1198923385, COSV51917451; called by muse, mutect2, varscan2
- STAT1 | c.2046C>T p.S682= | Silent (SNP) | VAF 26/374 reads (7%) | called by muse, mutect2
- STK11IP | c.3057G>T p.L1019= | Silent (SNP) | VAF 18/390 reads (5%) | called by muse, mutect2
- STPG4 | c.51G>A p.L17= | Silent (SNP) | VAF 26/248 reads (10%) | catalogued as COSV99681243; called by muse, mutect2
- SUPT5H | c.508C>T p.L170= | Silent (SNP) | VAF 18/244 reads (7%) | called by muse, mutect2
- TMEM217 | c.69C>T p.I23= | Silent (SNP) | VAF 13/288 reads (5%) | catalogued as rs1299342244; called by muse, mutect2
- TMEM26 | c.903C>G p.L301= | Silent (SNP) | VAF 52/1186 reads (4%) | catalogued as rs376058228, COSV53262279; called by muse, mutect2
- TOM1L2 | c.402C>A p.L134= (on ENST00000379504 / NM_001350333.2; = p.L84= on NM_001033551.3) | Silent (SNP) | VAF 25/134 reads (19%) | called by muse, mutect2, varscan2
- TUBA1C | c.351C>T p.L117= | Silent (SNP) | VAF 34/355 reads (10%) | catalogued as rs201347417; called by muse, mutect2
- UNC13D | c.2796C>G p.L932= | Silent (SNP) | VAF 12/404 reads (3%) | catalogued as rs1350575137; called by muse, mutect2
- WDR35 | c.3516C>T p.F1172= (on ENST00000345530 / NM_001006657.2; = p.F1161= on NM_020779.4) | Silent (SNP) | VAF 38/288 reads (13%) | called by muse, mutect2, varscan2
- ZKSCAN8 | c.504C>T p.L168= | Silent (SNP) | VAF 33/173 reads (19%) | called by muse, mutect2, varscan2
- ZNF521 | c.1467C>G p.L489= | Silent (SNP) | VAF 29/555 reads (5%) | catalogued as COSV100833047, COSV64125023; called by muse, mutect2
- ZNF583 | c.1443A>G p.Q481= | Silent (SNP) | VAF 89/333 reads (27%) | catalogued as rs1220781560; called by muse, mutect2, varscan2
- ABCG5 | c.-51G>A | 5'UTR (SNP) | VAF 86/470 reads (18%) | catalogued as rs751185544; called by muse, mutect2, varscan2
- ACAT2 | chr6:159761504 G>C | 5'Flank (SNP) | VAF 7/70 reads (10%) | called by muse, mutect2
- ADAM9 | c.*944G>C | 3'UTR (SNP) | VAF 8/61 reads (13%) | called by muse, mutect2, varscan2
- AFG3L2 | c.-108C>T | 5'UTR (SNP) | VAF 6/41 reads (15%) | catalogued as rs922603026; called by muse, mutect2
- AIFM1 | c.249+14C>T | Intron (SNP) | VAF 70/300 reads (23%) | called by muse, mutect2, varscan2
- AL109984.1 | n.186+1186C>A | Intron (SNP) | VAF 118/718 reads (16%) | called by muse, mutect2, varscan2
- ALX4 | c.-45C>A | 5'UTR (SNP) | VAF 14/98 reads (14%) | called by muse, varscan2
- ANKRD42 | c.-139G>T | 5'UTR (SNP) | VAF 162/540 reads (30%) | called by muse, mutect2, varscan2
- ARHGAP5 | c.-300G>A | 5'UTR (SNP) | VAF 9/203 reads (4%) | catalogued as rs898836056; called by muse, mutect2
- BRAF | c.-24C>G | 5'UTR (SNP) | VAF 9/42 reads (21%) | catalogued as rs1407485613; called by muse, mutect2, varscan2
- C10orf90 | c.1243+1195G>A | Intron (SNP) | VAF 14/96 reads (15%) | catalogued as COSV99504648; called by muse, mutect2
- C4orf3 | c.*38G>C | 3'UTR (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2
- CACNB3 | c.-15G>A | 5'UTR (SNP) | VAF 30/102 reads (29%) | catalogued as rs1287174649; called by muse, mutect2, varscan2
- CADM1 | c.1079-12115C>G | Intron (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- CCHCR1 | c.-51-342C>T | Intron (SNP) | VAF 34/300 reads (11%) | called by muse, mutect2, varscan2
- CMAHP | n.1939C>G | RNA (SNP) | VAF 24/207 reads (12%) | called by muse, mutect2, varscan2
- CNGA3 | c.215+291G>C | Intron (SNP) | VAF 5/78 reads (6%) | called by muse, mutect2
- CRYZL1 | c.-7+1537G>A | Intron (SNP) | VAF 29/174 reads (17%) | called by muse, mutect2, varscan2
- DDX23 | c.1383-680C>T | Intron (SNP) | VAF 7/23 reads (30%) | catalogued as rs1303436999; called by muse, mutect2, varscan2
- GON4L | chr1:155747780 G>A | 3'Flank (SNP) | VAF 14/272 reads (5%) | called by muse, mutect2
- HLA-J | n.1200+169G>A | Intron (SNP) | VAF 25/154 reads (16%) | catalogued as rs753316683; called by muse, mutect2, varscan2
- KARS1 | c.1552-14C>G | Intron (SNP) | VAF 16/360 reads (4%) | called by muse, mutect2
- KCTD1 | c.-15-46486C>T | Intron (SNP) | VAF 147/599 reads (25%) | called by muse, mutect2, varscan2
- KY | c.1090+122C>A | Intron (SNP) | VAF 15/509 reads (3%) | called by muse, mutect2
- MMS19 | c.262+45C>T | Intron (SNP) | VAF 58/221 reads (26%) | called by muse, mutect2, varscan2
- NCOA1 | c.4156-152C>G | Intron (SNP) | VAF 36/148 reads (24%) | called by mutect2, varscan2
- PDE4B | c.281+74181G>T | Intron (SNP) | VAF 21/403 reads (5%) | catalogued as COSV58468998; called by muse, mutect2
- PRKCG | c.*46C>T | 3'UTR (SNP) | VAF 52/366 reads (14%) | catalogued as rs532448095; called by mutect2, varscan2
- PSTK | c.*40G>A | 3'UTR (SNP) | VAF 13/70 reads (19%) | called by muse, mutect2
- PTPRN2 | c.2344+5949G>C | Intron (SNP) | VAF 30/392 reads (8%) | called by muse, mutect2
- RGSL1 | c.301+621G>A | Intron (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- RLN3 | c.191-366C>T | Intron (SNP) | VAF 12/88 reads (14%) | called by muse, varscan2
- RNF170 | c.-8+164G>A | Intron (SNP) | VAF 11/88 reads (13%) | called by muse, varscan2
- RNF170 | c.-8+105G>A | Intron (SNP) | VAF 23/146 reads (16%) | catalogued as rs1335536657; called by muse, varscan2
- SETBP1 | c.540+7314G>C | Intron (SNP) | VAF 15/168 reads (9%) | called by muse, mutect2
- SNX24 | c.442+37G>A | Intron (SNP) | VAF 10/189 reads (5%) | called by muse, mutect2
- SPSB3 | c.126+89C>T | Intron (SNP) | VAF 113/535 reads (21%) | called by muse, mutect2, varscan2
- TNPO2 | c.-13-358C>T | Intron (SNP) | VAF 15/65 reads (23%) | catalogued as COSV63509647; called by muse, mutect2, varscan2
- TOX2 | c.*173G>A | 3'UTR (SNP) | VAF 91/526 reads (17%) | called by muse, mutect2, varscan2
- TTLL11 | c.1539+60C>G | Intron (SNP) | VAF 15/136 reads (11%) | catalogued as COSV58641550, COSV58644546; called by muse, mutect2, varscan2
- VAPB | c.*3385G>A | 3'UTR (SNP) | VAF 140/523 reads (27%) | called by muse, mutect2, varscan2
- VAPB | c.*4661G>C | 3'UTR (SNP) | VAF 82/482 reads (17%) | called by muse, varscan2
- VRK3 | chr19:49972669 C>T | 3'Flank (SNP) | VAF 65/302 reads (22%) | called by muse, mutect2, varscan2
- YPEL1 | c.118-10C>T | Intron (SNP) | VAF 16/122 reads (13%) | catalogued as rs766360593; called by muse, mutect2, varscan2
- ZC3H14 | c.*9608C>T | 3'UTR (SNP) | VAF 29/149 reads (19%) | called by muse, mutect2, varscan2
- ZNF687 | chr1:151281649 G>A | 5'Flank (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- ZNF783 | c.*204G>C | 3'UTR (SNP) | VAF 8/165 reads (5%) | called by muse, mutect2
- ZNRF1 | c.*33-35G>C | Intron (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
